Somatic mutation profile of tumor specimen 0DELKP from CCDI case PBBMYK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 10.8 years (3,960 days).
Specimen 0DELKP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb34e5cb-c6d8-4544-af96-552f9a05808e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DELJ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56159bd2-4558-4703-95c7-1b2c1808bf38

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IDUA | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs138826105, COSV56102190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OSMR | c.2741G>C p.S914T | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CELSR1 | c.4881C>T p.D1627= | Silent (SNP) | VAF 29/231 reads (13%) | catalogued as rs771465230, COSV53083824; called by muse, mutect2, varscan2
- NOP2 | c.1098C>T p.Y366= (on ENST00000322166 / NM_001258308.2; = p.Y362= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/217 reads (17%) | called by muse, mutect2, varscan2
- COPS2 | c.715+50T>A | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, varscan2
- CWF19L1 | c.505-74A>G | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- EDRF1 | c.3394-71C>T | Intron (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, varscan2
